Somatic mutation profile of tumor specimen CDDP-ABJZ-TTP1-A (aliquot CDDP-ABJZ-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJZ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64 years.
Specimen CDDP-ABJZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93a7ebb6-246a-432f-8e97-cd038188bb75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJZ-NB1-A (Blood Derived Normal), aliquot CDDP-ABJZ-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9726306e-6eb4-4c4c-b3a0-1e04ba1510f9

The open-access MAF lists 297 somatic variants for this specimen: 194 protein-altering or splice-affecting, 54 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 54, Intron 24, 3'UTR 7, Nonsense Mutation 7, RNA 7, Splice Site 6, Frame Shift Del 6, 5'UTR 5, 5'Flank 5, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 126/272 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 42/262 reads (16%) | catalogued as COSV54036344; called by muse, mutect2, varscan2
- ABLIM3 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58647841; called by muse, mutect2, varscan2
- ACTL9 | c.365G>C p.W122S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61007016; called by muse, mutect2
- ADAMTS12 | c.4183C>T p.R1395W | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1397116841, COSV100710140, COSV61260435; called by muse, mutect2, varscan2
- ALMS1 | c.6968C>G p.T2323R | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV52520158; called by muse, mutect2, varscan2
- ARL15 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV72289009, COSV72292373; called by muse, mutect2, varscan2
- ARSK | c.1308G>T p.L436F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1043157588; called by muse, varscan2
- ASH1L | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1409082408, COSV64212834; called by muse, mutect2
- ASXL3 | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1568361904, COSV52477412; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 112/383 reads (29%) | catalogued as COSV52271345; called by muse, mutect2, varscan2
- BCL9 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); catalogued as rs782395400, COSV52349284; called by muse, mutect2, varscan2
- BIRC6 | c.4654G>A p.G1552S | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV70201010, COSV70204615; called by muse, mutect2, varscan2
- C10orf71 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1340165668, COSV60512049; called by muse, mutect2, varscan2
- C1GALT1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs200796468, COSV56180260; called by muse, mutect2, varscan2
- CACNA1G | c.3398C>A p.S1133* | Nonsense Mutation (SNP) | VAF 55/485 reads (11%) | catalogued as COSV104415865; called by muse, mutect2, varscan2
- CCDC175 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV55793242; called by muse, mutect2, varscan2
- CCDC71 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV58910707; called by muse, mutect2, varscan2
- CCER1 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62648467; called by mutect2, varscan2
- CNTN3 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV55170552, COSV55182356; called by muse, mutect2, varscan2
- COL13A1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.823); catalogued as rs763334782; called by muse, mutect2, varscan2
- COL6A5 | c.3397C>A p.L1133I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.499); catalogued as COSV55214380; called by muse, mutect2, varscan2
- COL9A3 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751668107, COSV59654792, COSV59655641; called by muse, mutect2, varscan2
- CRISP3 | c.88C>A p.P30T (on ENST00000371159 / NM_001368123.1; = p.P22T on NM_001190986.2) | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.006); catalogued as COSV53822712; called by muse, mutect2, varscan2
- CSMD3 | c.8884G>A p.D2962N (on ENST00000297405 / NM_001363185.1; = p.D2793N on NM_052900.3) | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV52135448, COSV52295863; called by muse, mutect2, varscan2
- CSTF2 | c.1030A>G p.R344G | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65895069; called by muse, mutect2, varscan2
- CTNNA3 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57718674, COSV57721676; called by muse, mutect2, varscan2
- CYLC2 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV66339179; called by muse, mutect2, varscan2
- CYLC2 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1288946403, COSV66339183; called by muse, mutect2, varscan2
- DCBLD2 | c.1127A>C p.Y376S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58792699; called by muse, mutect2, varscan2
- DCST2 | c.1861G>A p.G621S | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs200561857; called by muse, mutect2
- DPPA2 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV72118290; called by muse, mutect2, varscan2
- DYNC1LI1 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56128860; called by muse, mutect2, varscan2
- EPG5 | c.5350G>C p.D1784H | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV56355107; called by muse, mutect2, varscan2
- EPHA1 | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV51975758; called by muse, mutect2, varscan2
- EPN1 | c.1680del p.M561* (on ENST00000270460 / NM_001321263.1; = p.M535* on NM_013333.3) | Frame Shift Del (DEL) | VAF 22/115 reads (19%) | catalogued as rs1306515040; called by mutect2, pindel
- EPS15 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65532558; called by muse, mutect2, varscan2
- ERBB4 | c.1268T>C p.I423T | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377040748; called by muse, mutect2, varscan2
- FAM114A2 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59457284; called by muse, mutect2, varscan2
- FAM135B | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50537682; called by muse, mutect2, varscan2
- FAM53A | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV57403186; called by muse, mutect2, varscan2
- FAT4 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs910813145, COSV67897913; called by muse, mutect2, varscan2
- FBLN1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs1321656737, COSV53045658, COSV53051007, COSV99410689; called by muse, mutect2
- FBXO4 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55853909; called by muse, mutect2, varscan2
- FEZ1 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54031417; called by muse, mutect2, varscan2
- FNDC1 | c.2066C>A p.P689H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV51946273; called by muse, mutect2, varscan2
- FZD6 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV62472466; called by muse, mutect2, varscan2
- GCM1 | c.862T>A p.Y288N | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.467); catalogued as COSV52523720; called by muse, mutect2, varscan2
- GP2 | c.1547G>C p.S516T (on ENST00000381362 / NM_001007240.3; = p.S513T on NM_001502.4) | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56896276; called by muse, mutect2, varscan2
- GPR25 | c.730C>G p.R244G | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58498153, COSV58499041; called by muse, mutect2, varscan2
- GRID2 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as COSV56255602; called by muse, mutect2, varscan2
- GRK1 | c.843C>A p.N281K | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV59554074; called by muse, mutect2, varscan2
- GSG1 | c.396T>G p.F132L | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs761230670, COSV60973142; called by muse, mutect2, varscan2
- H2BC21 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 317/595 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.267); catalogued as COSV58613072, COSV58613332; called by muse, mutect2, varscan2
- HADHA | c.1496A>C p.Y499S | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66108521; called by muse, mutect2, varscan2
- HBA2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 102/603 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs33987053, CD120277, CM870033, COSV52406851; called by muse, mutect2, varscan2
- HDAC9 | c.3076G>C p.A1026P (on ENST00000441542 / NM_178425.3; = p.A1023P on NM_178423.3) | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67783602; called by muse, mutect2, varscan2
- HIP1R | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53444405; called by muse, mutect2, varscan2
- HS3ST4 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.048); catalogued as COSV58828558; called by muse, mutect2, varscan2
- IFI16 | c.1605G>T p.E535D (on ENST00000295809 / NM_001364867.2; = p.E479D on NM_001206567.2) | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV55539443; called by muse, mutect2, varscan2
- IFNA17 | c.486T>A p.C162* | Nonsense Mutation (SNP) | VAF 84/170 reads (49%) | catalogued as rs1319040341; called by muse, varscan2
- JAK1 | c.3402C>G p.F1134L | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs767652390, COSV53807354; called by muse, varscan2
- KCNH6 | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV59004222, COSV59007038; called by muse, mutect2, varscan2
- KCNN3 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55225270; called by muse, mutect2, varscan2
- KHDRBS1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56983521; called by muse, mutect2, varscan2
- KNSTRN | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as rs756907878, COSV51110129; called by muse, mutect2, varscan2
- KRT24 | c.1274A>G p.N425S | Missense Mutation (SNP) | VAF 184/602 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV52881745; called by muse, mutect2, varscan2
- KRT73 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59841351; called by muse, mutect2, varscan2
- KRTAP13-1 | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62664251; called by muse, mutect2, varscan2
- LRIF1 | c.1429A>G p.I477V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs2232042; called by muse, mutect2, varscan2
- LRP1B | c.12203A>G p.K4068R | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.793); catalogued as rs941891420, COSV67266294; called by muse, mutect2, varscan2
- LYPLA2 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65721002; called by muse, mutect2, varscan2
- MARCHF11 | c.1114G>T p.V372L | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV60133845; called by mutect2, varscan2
- MAST3 | c.2765del p.P922Rfs*103 | Frame Shift Del (DEL) | VAF 39/240 reads (16%) | catalogued as COSV53227238; called by mutect2, pindel, varscan2
- MED12L | c.5909G>T p.R1970I | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV56394082; called by muse, mutect2, varscan2
- MKI67 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV64076456; called by muse, mutect2, varscan2
- MNDA | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV63741931; called by muse, mutect2
- MOSPD2 | c.1342A>T p.S448C | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV66860759; called by muse, mutect2, varscan2
- MRGPRD | c.521G>C p.R174P | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58423230, COSV58424016; called by muse, mutect2, varscan2
- MROH2B | c.3457A>T p.T1153S | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV68188709; called by muse, mutect2, varscan2
- MROH9 | c.2447C>G p.P816R | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV63018246; called by muse, mutect2, varscan2
- MSH6 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV52286471; called by muse, mutect2, varscan2
- MTMR8 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.711); catalogued as COSV66395968; called by muse, mutect2
- MUC16 | c.14314C>A p.P4772T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV67488729; called by muse, mutect2, varscan2
- MUC17 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs752809236, COSV60300963; called by muse, mutect2, varscan2
- NACC2 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53202535; called by muse, mutect2, varscan2
- NBEA | c.6154G>T p.G2052C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59816467; called by muse, mutect2
- NUBPL | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 335/491 reads (68%) | catalogued as COSV55273908; called by muse, mutect2, varscan2
- NUP133 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV54574767; called by muse, mutect2, varscan2
- OR14K1 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51722218; called by muse, mutect2, varscan2
- OR2A2 | c.280G>C p.V94L | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs61729718, COSV68872437; called by muse, mutect2, varscan2
- OR2L8 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100594200, COSV61726384; called by muse, mutect2
- OR2T6 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63216969; called by muse, mutect2, varscan2
- OR56A5 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1379833449, COSV60827913; called by muse, mutect2, varscan2
- OR5P3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs117218570, COSV60429066, COSV60429677; called by muse, mutect2, varscan2
- OR6B1 | c.256T>C p.W86R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV68770566; called by muse, mutect2, varscan2
- PAK5 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.121); catalogued as COSV62036232; called by muse, mutect2, varscan2
- PAPPA2 | c.4305G>T p.Q1435H | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as COSV62809554; called by muse, mutect2, varscan2
- PHKA1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs1271854811, COSV59809296; called by muse, varscan2
- PIRT | c.224T>A p.L75* | Nonsense Mutation (SNP) | VAF 39/144 reads (27%) | catalogued as COSV74119951; called by muse, mutect2, varscan2
- PNPLA7 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52997971, COSV53005669, COSV99479812; called by muse, mutect2, varscan2
- POU2F1 | c.2057C>T p.T686I (on ENST00000541643 / NM_001365848.1; = p.T709I on NM_002697.4) | Missense Mutation (SNP) | VAF 114/374 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs745405885, COSV54823805, COSV99611396; called by muse, mutect2, varscan2
- PRDM11 | c.224C>G p.S75C (on ENST00000530656 / NM_001359633.1; = p.S41C on NM_001256695.1) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs770538714, COSV55443151; called by muse, mutect2, varscan2
- PRKCG | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54732092; called by muse, mutect2, varscan2
- QRICH1 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV62617420; called by muse, mutect2, varscan2
- RBM6 | c.2629G>A p.V877I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as rs1175509612, COSV56481503; called by muse, mutect2, varscan2
- REG3A | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as COSV59411520; called by muse, mutect2, varscan2
- RFC1 | c.1154A>T p.Y385F | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV62900892; called by muse, mutect2, varscan2
- RIMS2 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 223/449 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.99); catalogued as COSV68113301; called by muse, mutect2, varscan2
- ROBO1 | c.3182G>T p.G1061V | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV71397858; called by muse, mutect2, varscan2
- ROBO1 | c.2852G>T p.R951I | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV71397217, COSV71397859; called by muse, mutect2
- ROBO1 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71396531, COSV71397860; called by muse, mutect2, varscan2
- RPP38 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV65381444, COSV65381925; called by muse, mutect2, varscan2
- RTL1 | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV66017408; called by muse, mutect2, varscan2
- RTTN | c.4033-2A>G p.X1345_splice | Splice Site (SNP) | VAF 27/92 reads (29%) | catalogued as rs1040282375; called by muse, mutect2, varscan2
- SEMA3D | c.297C>G p.N99K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV52402590; called by muse, mutect2, varscan2
- SEZ6L | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV50681262; called by muse, mutect2, varscan2
- SHISA9 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV69641939; called by muse, mutect2, varscan2
- SLC1A7 | c.1509C>G p.I503M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV57016808, COSV57017139; called by muse, mutect2, varscan2
- SLC49A3 | c.135+8C>T | Splice Region (SNP) | VAF 22/202 reads (11%) | catalogued as rs1198746137; called by muse, mutect2, varscan2
- SLCO1B1 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57009624; called by muse, mutect2, varscan2
- SLCO5A1 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 108/199 reads (54%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1033706234, COSV52666758; called by muse, mutect2, varscan2
- SLITRK2 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV59423673; called by muse, mutect2, varscan2
- SMOC1 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM116124, COSV62763073; called by muse, varscan2
- SNX20 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV56059281; called by muse, mutect2, varscan2
- SORCS3 | c.2115C>A p.H705Q | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV63798027; called by muse, mutect2, varscan2
- SPRED1 | c.423+1G>T p.X141_splice | Splice Site (SNP) | VAF 71/146 reads (49%) | catalogued as CS075236; called by muse, mutect2, varscan2
- SRI | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56001524; called by muse, mutect2, varscan2
- ST3GAL2 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 32/69 reads (46%) | PolyPhen benign (0.018); catalogued as COSV61597974; called by mutect2, varscan2
- TAF2 | c.3506A>G p.H1169R | Missense Mutation (SNP) | VAF 43/498 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV65420560; called by muse, mutect2
- TAS1R2 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); catalogued as COSV64746863; called by muse, mutect2, varscan2
- TINF2 | c.1235A>T p.N412I | Missense Mutation (SNP) | VAF 94/680 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.576); catalogued as COSV57470116; called by muse, mutect2, varscan2
- TMEM161B | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56933543; called by muse, mutect2, varscan2
- TNRC6B | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753937261, COSV57303133; called by muse, mutect2
- TPPP2 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58795521; called by muse, mutect2
- TRPM2 | c.3436C>G p.Q1146E | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as COSV55975872; called by muse, mutect2, varscan2
- TSC22D1 | c.1066A>C p.T356P | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV71776227; called by muse, mutect2, varscan2
- TTN | c.92131C>T p.R30711C (on ENST00000591111; = p.R23287C on NM_003319.4) | Missense Mutation (SNP) | VAF 32/243 reads (13%) | PolyPhen probably damaging (0.998); catalogued as rs753874904, COSV59892033, COSV59956068; called by muse, mutect2, varscan2
- TTN | c.87607A>G p.K29203E (on ENST00000591111; = p.K21779E on NM_003319.4) | Missense Mutation (SNP) | VAF 57/386 reads (15%) | PolyPhen benign (0.169); catalogued as COSV60296140; called by muse, mutect2, varscan2
- TTN | c.65287G>C p.E21763Q (on ENST00000591111; = p.E14339Q on NM_003319.4) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | PolyPhen possibly damaging (0.698); catalogued as COSV60296180; called by muse, mutect2, varscan2
- UMOD | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56779113; called by muse, mutect2, varscan2
- UNC80 | c.8447T>A p.L2816Q | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55903740; called by muse, mutect2, varscan2
- WAC | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61569454; called by muse, mutect2, varscan2
- ZBED6 | c.2631G>T p.E877D | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.879); catalogued as COSV59749715; called by muse, mutect2, varscan2
- ZFHX4 | c.10285G>T p.G3429C | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50617551, COSV51491543; called by muse, mutect2, varscan2
- ZNF229 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV52160948; called by muse, mutect2, varscan2
- ZNF512B | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as rs375990139, COSV53872343, COSV53877499; called by muse, mutect2, varscan2
- ZNF703 | c.1655A>T p.H552L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.793); catalogued as COSV58999393; called by muse, mutect2, varscan2
- ZNF831 | c.428A>T p.K143M | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100925728, COSV64044530; called by muse, mutect2, varscan2
- ZNF99 | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV68054631; called by muse, mutect2, varscan2
- ADAM10 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ADGRV1 | c.14633C>A p.P4878Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.1); called by muse, varscan2
- ATM | c.7516-2A>G p.X2506_splice | Splice Site (SNP) | VAF 79/163 reads (48%) | called by muse, mutect2, varscan2
- BMS1 | c.3715G>T p.A1239S | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.028); called by muse, mutect2
- C2CD5 | c.163T>C p.W55R | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CBARP | c.908G>C p.G303A (on ENST00000382477; = p.G283A on NM_152769.3) | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CENPC | c.611A>T p.K204I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CROCC2 | c.3653G>T p.G1218V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CTU1 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CUBN | c.5896C>T p.P1966S | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DPRX | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- EPHA5 | c.523del p.D175Ifs*19 | Frame Shift Del (DEL) | VAF 36/220 reads (16%) | called by mutect2, pindel, varscan2
- FAM214B | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMO1 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HECTD4 | c.9500G>T p.C3167F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, varscan2
- IKBKE | c.1693G>T p.G565W | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KAT5 | c.79+1G>A p.X27_splice | Splice Site (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- KCNA4 | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LRP1B | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAPK8IP1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCM3AP | c.281_282del p.V94Gfs*17 | Frame Shift Del (DEL) | VAF 68/201 reads (34%) | called by pindel, varscan2
- MYO5B | c.5078C>T p.T1693I | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, varscan2
- NDST4 | c.1943A>G p.Y648C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NEK11 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2
- NIBAN3 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NKX2-3 | c.726C>G p.S242R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- NMNAT1 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPY | c.107dup p.E38Rfs*55 | Frame Shift Ins (INS) | VAF 46/205 reads (22%) | called by mutect2, pindel, varscan2
- OR5H6 | c.752G>C p.R251P (on ENST00000642105; = p.R235P on NM_001005479.2) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PGBD1 | c.870-2A>T p.X290_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | called by muse, varscan2
- PHF1 | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PHKA1 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLOD1 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- POTEF | c.1596+1G>C p.X532_splice | Splice Site (SNP) | VAF 18/110 reads (16%) | called by mutect2, varscan2
- PRAMEF14 | c.1122C>A p.S374R | Missense Mutation (SNP) | VAF 62/451 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- RBM26 | c.1949C>T p.P650L (on ENST00000438737 / NM_001366735.2; = p.P647L on NM_022118.5) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- RBM45 | c.1416del p.Q473Kfs*7 (on ENST00000616198 / NM_001365579.1; = p.Q471Kfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- RP1L1 | c.5890_5891insT p.Q1964Lfs*20 | Frame Shift Ins (INS) | VAF 36/219 reads (16%) | called by mutect2, pindel, varscan2
- SEPTIN5 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SH3GL3 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC13B | c.3037del p.Q1013Kfs*3 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- UNC13C | c.4514A>G p.N1505S | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- WDR43 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ZEB2 | c.942C>G p.N314K | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS12 | c.2805C>A p.L935= | Silent (SNP) | VAF 72/209 reads (34%) | catalogued as COSV61276291; called by muse, mutect2, varscan2
- APOL2 | c.423A>T p.T141= | Silent (SNP) | VAF 36/213 reads (17%) | catalogued as COSV50772964; called by muse, mutect2, varscan2
- ARHGAP31 | c.2007C>G p.L669= | Silent (SNP) | VAF 43/228 reads (19%) | catalogued as rs907358023, COSV51797970; called by muse, mutect2, varscan2
- ARL14EPL | c.405C>T p.I135= | Silent (SNP) | VAF 80/207 reads (39%) | catalogued as rs1345250271, COSV74124124; called by muse, mutect2, varscan2
- BTRC | c.60C>T p.P20= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV64562996; called by muse, mutect2, varscan2
- CABP5 | c.147T>C p.S49= | Silent (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- CBX8 | c.898C>T p.L300= | Silent (SNP) | VAF 70/284 reads (25%) | catalogued as COSV53937456; called by muse, mutect2, varscan2
- CDHR2 | c.3405G>A p.L1135= | Silent (SNP) | VAF 48/297 reads (16%) | catalogued as rs1561882332, COSV56144157; called by muse, mutect2, varscan2
- CEP350 | c.4920G>A p.K1640= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV62608875; called by muse, mutect2, varscan2
- CNDP1 | c.90G>T p.P30= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV62595106; called by muse, mutect2, varscan2
- CRISPLD1 | c.1029T>C p.Y343= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as rs921699577, COSV51552481; called by muse, mutect2, varscan2
- CUX2 | c.3072C>T p.S1024= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs778511615, COSV55645491; called by muse, mutect2, varscan2
- CYP11B1 | c.966C>A p.P322= | Silent (SNP) | VAF 38/204 reads (19%) | catalogued as COSV52829927; called by muse, mutect2, varscan2
- DTNA | c.1554C>A p.L518= | Silent (SNP) | VAF 131/399 reads (33%) | catalogued as COSV52022565; called by muse, mutect2, varscan2
- DYSF | c.2451C>A p.S817= | Silent (SNP) | VAF 49/367 reads (13%) | catalogued as COSV50545209, COSV99243412; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.529C>T p.L177= | Silent (SNP) | VAF 78/168 reads (46%) | catalogued as rs1439321695, COSV57517825; called by muse, mutect2, varscan2
- EPHA7 | c.1111C>A p.R371= | Silent (SNP) | VAF 48/220 reads (22%) | catalogued as COSV65190033; called by muse, mutect2, varscan2
- FREM1 | c.2838G>T p.V946= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV66528924; called by muse, mutect2, varscan2
- GALR1 | c.111G>T p.L37= | Silent (SNP) | VAF 53/291 reads (18%) | called by muse, mutect2, varscan2
- GBP2 | c.1680G>A p.K560= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV65068560; called by muse, mutect2, varscan2
- GJD4 | c.168G>T p.T56= | Silent (SNP) | VAF 104/327 reads (32%) | catalogued as COSV58703298; called by muse, mutect2, varscan2
- HABP2 | c.1389G>A p.Q463= | Silent (SNP) | VAF 87/244 reads (36%) | catalogued as COSV63493061, COSV63493438; called by muse, mutect2, varscan2
- HEATR5A | c.3498A>G p.K1166= | Silent (SNP) | VAF 23/217 reads (11%) | catalogued as COSV66344857; called by muse, mutect2, varscan2
- HTATSF1 | c.2139C>G p.S713= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV54480858; called by muse, mutect2, varscan2
- INTS1 | c.246C>T p.S82= | Silent (SNP) | VAF 93/310 reads (30%) | catalogued as rs1039437436, COSV67179404; called by muse, mutect2, varscan2
- LRP10 | c.2049G>A p.L683= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV62078837; called by muse, mutect2, varscan2
- LRRTM4 | c.1464C>T p.Y488= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs769800425, COSV69141727; called by muse, mutect2, varscan2
- LTBP3 | c.222C>T p.T74= | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as COSV100098719, COSV57240557, COSV57243636; called by muse, mutect2, varscan2
- MXRA5 | c.7359G>T p.R2453= | Silent (SNP) | VAF 47/77 reads (61%) | catalogued as COSV54235452, COSV54247716; called by muse, mutect2, varscan2
- NUP210 | c.897G>T p.P299= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as rs763099751, COSV54406262, COSV54412774; called by muse, mutect2, varscan2
- OR4C13 | c.168C>A p.P56= | Silent (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- PASD1 | c.414T>C p.C138= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV64857337; called by muse, mutect2, varscan2
- PHF1 | c.144G>A p.L48= | Silent (SNP) | VAF 31/268 reads (12%) | called by muse, mutect2, varscan2
- POLR1F | c.297G>T p.V99= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55999444; called by muse, mutect2, varscan2
- PPP4R3B | c.1863A>T p.A621= (on ENST00000616407 / NM_001122964.3; = p.A536= on NM_020463.4) | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs1390709299, COSV55408534; called by muse, mutect2, varscan2
- PSKH2 | c.99G>C p.G33= | Silent (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- PTN | c.246C>A p.T82= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100780810, COSV61966170; called by muse, mutect2, varscan2
- SAMSN1 | c.789C>T p.Y263= (on ENST00000647101; = p.Y35= on NM_001256370.1) | Silent (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- SMO | c.396C>T p.P132= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as COSV50840390; called by muse, mutect2, varscan2
- SOX13 | c.750C>T p.P250= | Silent (SNP) | VAF 45/184 reads (24%) | catalogued as rs544550219, COSV65827433; called by muse, mutect2, varscan2
- SPTA1 | c.4779T>A p.L1593= | Silent (SNP) | VAF 62/571 reads (11%) | catalogued as COSV63749083, COSV63749088; called by muse, mutect2, varscan2
- STARD8 | c.2745A>T p.A915= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV52931840; called by muse, mutect2, varscan2
- SYNRG | c.153T>G p.P51= | Silent (SNP) | VAF 125/276 reads (45%) | called by muse, mutect2, varscan2
- TASOR | c.144C>T p.I48= | Silent (SNP) | VAF 40/328 reads (12%) | catalogued as rs955816938, COSV62929454; called by muse, mutect2, varscan2
- TCFL5 | c.942G>A p.T314= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV53897176; called by muse, mutect2, varscan2
- TCP11L2 | c.1008G>C p.L336= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV54432126; called by muse, mutect2, varscan2
- TEKT2 | c.217C>A p.R73= | Silent (SNP) | VAF 62/388 reads (16%) | catalogued as rs748985076, COSV52882032; called by muse, mutect2, varscan2
- THEM4 | c.411A>G p.L137= | Silent (SNP) | VAF 122/233 reads (52%) | catalogued as COSV100916938; called by muse, mutect2, varscan2
- TRPV5 | c.1647G>A p.V549= | Silent (SNP) | VAF 28/175 reads (16%) | catalogued as COSV54689189; called by muse, mutect2, varscan2
- WDR87 | c.3819T>A p.A1273= | Silent (SNP) | VAF 65/151 reads (43%) | catalogued as COSV58205531; called by muse, mutect2, varscan2
- ZNF362 | c.609G>T p.G203= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as COSV65031904; called by muse, mutect2, varscan2
- ZNF536 | c.3732C>A p.P1244= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV62832852, COSV62836799; called by muse, mutect2, varscan2
- ZNF804A | c.2586T>A p.V862= | Silent (SNP) | VAF 77/246 reads (31%) | catalogued as COSV56467916; called by muse, mutect2, varscan2
- ZP1 | c.123C>T p.Y41= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs186019767; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4592G>T | Intron (SNP) | VAF 25/188 reads (13%) | catalogued as rs966519983; called by muse, mutect2, varscan2
- ACBD4 | c.503-32T>G | Intron (SNP) | VAF 40/145 reads (28%) | catalogued as COSV100416037, COSV58853341; called by muse, mutect2, varscan2
- C16orf97 | n.35A>G | RNA (SNP) | VAF 18/40 reads (45%) | catalogued as rs1205560811; called by muse, mutect2, varscan2
- C19orf12 | chr19:29715297 G>T | 5'Flank (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- CDH13 | c.45+78046C>A | Intron (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- CLPSL2 | c.*28C>A | 3'UTR (SNP) | VAF 21/107 reads (20%) | catalogued as COSV64610209; called by muse, mutect2, varscan2
- CYP2S1 | c.*70G>A | 3'UTR (SNP) | VAF 51/214 reads (24%) | catalogued as COSV100027548; called by muse, mutect2, varscan2
- DCDC1 | c.5074-2185G>C | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- DNMT3A | c.640-1421A>G | Intron (SNP) | VAF 50/156 reads (32%) | catalogued as COSV53074024; called by muse, mutect2, varscan2
- DPPA3 | c.-5C>T | 5'UTR (SNP) | VAF 39/122 reads (32%) | catalogued as rs935067596, COSV61502802; called by muse, mutect2, varscan2
- EYS | c.1767-6579_1767-6577dup | Intron (INS) | VAF 50/606 reads (8%) | called by mutect2, pindel
- EYS | c.1766+2578G>C | Intron (SNP) | VAF 28/169 reads (17%) | catalogued as COSV60998203; called by muse, mutect2, varscan2
- FOXN4 | c.597-46T>A | Intron (SNP) | VAF 17/59 reads (29%) | called by muse, varscan2
- GABRG2 | c.1249-1310G>C | Intron (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- GVINP1 | n.2007A>T | RNA (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- HK1 | c.1719+39A>G | Intron (SNP) | VAF 88/293 reads (30%) | catalogued as rs377533672; called by muse, mutect2, varscan2
- IL7R | c.801-12C>G | Intron (SNP) | VAF 194/360 reads (54%) | called by muse, mutect2, varscan2
- ITGA6 | c.3232-2226A>G | Intron (SNP) | VAF 57/198 reads (29%) | catalogued as rs1282990496; called by muse, mutect2, varscan2
- LILRB2 | c.1360+75C>A | Intron (SNP) | VAF 14/120 reads (12%) | catalogued as rs975505572; called by muse, mutect2, varscan2
- MANBA | c.-19G>T | 5'UTR (SNP) | VAF 48/241 reads (20%) | called by muse, mutect2, varscan2
- MAP3K15 | c.*48T>G | 3'UTR (SNP) | VAF 36/47 reads (77%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+5436G>A | Intron (SNP) | VAF 78/228 reads (34%) | catalogued as rs752769688; called by muse, mutect2, varscan2
- MKRN9P | n.424C>A | RNA (SNP) | VAF 44/271 reads (16%) | called by muse, mutect2, varscan2
- MYH16 | n.4093G>A | RNA (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- NBR2 | n.408G>T | RNA (SNP) | VAF 162/629 reads (26%) | called by muse, mutect2, varscan2
- NRXN1 | c.*24del | 3'UTR (DEL) | VAF 23/97 reads (24%) | called by mutect2, pindel, varscan2
- NRXN1 | c.4039-30232G>T | Intron (SNP) | VAF 21/154 reads (14%) | called by muse, mutect2, varscan2
- PCDH11X | c.3033+3642C>G | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100013906; called by muse, mutect2, varscan2
- PLCH2 | c.2959+209C>A | Intron (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- PRDM15 | c.-731G>T | 5'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- RBM42 | c.442+24del | Intron (DEL) | VAF 26/159 reads (16%) | called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34159536 C>T | 5'Flank (SNP) | VAF 30/72 reads (42%) | catalogued as rs1450593222; called by muse, mutect2, varscan2
- SEPTIN1 | c.*199G>T | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-4 | n.57G>T | RNA (SNP) | VAF 36/207 reads (17%) | catalogued as rs1336939857; called by muse, mutect2, varscan2
- SPATA31C2 | n.2617C>A | RNA (SNP) | VAF 54/309 reads (17%) | catalogued as rs774781268; called by muse, mutect2, varscan2
- SRP19 | c.*1377C>A | 3'UTR (SNP) | VAF 30/162 reads (19%) | catalogued as COSV99810123; called by muse, varscan2
- SSPOP | n.15119+10G>T | Intron (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- SUMF2 | c.396+74A>T | Intron (SNP) | VAF 39/312 reads (13%) | called by muse, mutect2, varscan2
- TARS1 | c.330-894G>T | Intron (SNP) | VAF 37/190 reads (19%) | catalogued as COSV54311968; called by muse, mutect2, varscan2
- TTLL7 | c.2369+3063A>T | Intron (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- TWF1 | c.25+195G>A | Intron (SNP) | VAF 36/228 reads (16%) | called by muse, mutect2, varscan2
- USP2 | chr11:119381842 C>G | 5'Flank (SNP) | VAF 84/222 reads (38%) | called by muse, mutect2, varscan2
- USP2 | chr11:119381843 G>A | 5'Flank (SNP) | VAF 83/220 reads (38%) | called by muse, mutect2, varscan2
- Unknown | chr17:73823794 G>T | IGR (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- WDFY4 | c.5982+708C>A | Intron (SNP) | VAF 37/183 reads (20%) | called by muse, mutect2, varscan2
- WT1 | chr11:32435783 C>T | 5'Flank (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1266T>C | 3'UTR (SNP) | VAF 49/155 reads (32%) | catalogued as COSV54729515; called by muse, mutect2, varscan2
- ZNF454 | c.-57A>G | 5'UTR (SNP) | VAF 12/68 reads (18%) | catalogued as rs1438746524; called by muse, mutect2, varscan2
- ZP2 | c.-47C>T | 5'UTR (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
